Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3363, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3363-01A (Primary Tumor).

[page 1 of 2]
TEST: Surgical Pathology

Collected Date & Time:

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Left renal mass

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Received in formalin labeled [REDACTED] - left kidney and adrenal" is a 342 gram nephrectomy specimen consisting of a 12.2 x 6.4 x 2.7 cm kidney and a moderate amount of attached perinephric fat. There is a 5.2 x 1.7 x 1.1 cm adrenal gland in the upper portion of the attached fat. At the hilum is a 2.7 x 0.2 cm segment of ureter, a 0.8 x 0.4 cm segment of renal artery, and a 0.5 x 0.3 cm segment of renal vein. The capsule is smooth and tan-red. There is a 10.7 x 7.6 x 1.7 cm shaggy tan-yellow to red mass in the upper pole, which appears to abut the capsule and is 0.5 cm from the inked perinephric fat margin. The cut surfaces of the mass consist of focally cystic friable tan-red to yellow tissue. The mass does not involve the renal vein margin. The remainder of the kidney consists of red-brown parenchyma. The corticomedullary junction is ill-defined. No additional lesions are identified. The cut surface of the adrenal is hemorrhagic. The specimen is inked, serially sectioned, and representative sections submitted as follows: A - ureterovascular margin; B - mass to uninvolved parenchyma; C - mass to perinephric fat; D-E - mass to inked margin; F-G - uninvolved parenchyma; H-I - adrenal. Also received in the same container is a blue, green and yellow cassette labeled [REDACTED] for genomic research study.

Microscopic Description:

Slides are reviewed labeled [REDACTED].

Final Diagnosis

Left kidney and left adrenal:

Renal cell carcinoma, clear cell type.

Site: Neoplasm is identified in the upper pole of the kidney.

Tumor size: 10.7 x 7.6 x 1.7 cm.

Extent of the tumor: Neoplasm is confined to the kidney and does not extend into major vessels.

Nuclear grade:

Fuhrman grade: 2/4.

Lymphovascular space invasion: No.

Transcapsular invasion: No.

Renal vein invasion: No.

Venal caval invasion: Not resected.

Adrenal gland: The adrenal gland is not involved by neoplasm.

Surgical margin status:

Soft tissue margin: Negative

Ureteral margin: Negative.

Vascular margin: Negative.

Lymph node status: No lymph nodes removed for examination.

Other:

Chronic pyelonephritis.

Nephrocalcinosis.

Vascular wall thickening consistent with arteriolonephrosclerosis.

Stage: pT2NXMX.

PAS 9 SPC-A

CPT: 88307 x 2

Comments

Path stage: pT2 Nx Mx

[page 2 of 2]
[REDACTED]

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED], who concurs with the diagnosis.

This test has been finalized at the [REDACTED]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file aafa6653-aa95-48b8-86c1-e44e4fe2f215 (TCGA-A3-3363.80D06D79-1EFF-466F-9F07-6FA7C829E5D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).